Somatic mutation profile of tumor specimen TCGA-CC-A9FV-01A (aliquot TCGA-CC-A9FV-01A-11D-A36X-10) from TCGA case TCGA-CC-A9FV, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 57.6 years (21,044 days).
Specimen TCGA-CC-A9FV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1aae7ad5-114a-4175-a31c-5ddc1372f478.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A9FV-10A (Blood Derived Normal), aliquot TCGA-CC-A9FV-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0818c9f4-2beb-46d7-a430-77f884f821d0

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Splice Site 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C6orf62 | c.119T>G p.F40C | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100965847; called by muse, mutect2, varscan2
- DDX47 | c.349T>G p.S117A | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV100774444; called by muse, mutect2, varscan2
- FANCB | c.2260T>A p.F754I | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV100146288; called by muse, mutect2
- FSHR | c.153-1G>A p.X51_splice | Splice Site (SNP) | VAF 11/70 reads (16%) | catalogued as COSV100436740, COSV58621791; called by muse, mutect2, varscan2
- GZMA | c.627T>C p.N209= | Splice Region (SNP) | VAF 19/139 reads (14%) | catalogued as rs1469343517, COSV99696347; called by muse, mutect2, varscan2
- MTA1 | c.1064A>G p.Y355C | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100494803; called by muse, mutect2, varscan2
- NDUFB3 | c.70A>G p.I24V | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT tolerated (0.84); PolyPhen benign (0.182); catalogued as COSV99428256; called by muse, mutect2
- RNF213 | c.15435A>C p.Q5145H | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.387); catalogued as COSV100299320; called by muse, mutect2, varscan2
- SEL1L3 | c.285C>A p.N95K | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99339074; called by muse, mutect2, varscan2
- SMARCD2 | c.1015A>G p.I339V | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.217); catalogued as rs895825903, COSV99856136; called by muse, mutect2, varscan2
- SSTR3 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60729997; called by muse, mutect2
- TRMT13 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.083); catalogued as COSV99790458; called by muse, mutect2
- HK2 | c.1836C>T p.D612= | Silent (SNP) | VAF 12/121 reads (10%) | catalogued as rs200225889; called by muse, mutect2, varscan2
- NCMAP | c.216C>T p.T72= | Silent (SNP) | VAF 18/157 reads (11%) | catalogued as rs373926438; called by muse, mutect2, varscan2
- TIGD3 | c.1248C>T p.D416= | Silent (SNP) | VAF 8/109 reads (7%) | catalogued as rs757126205, COSV52889916; called by muse, mutect2
- ZNF205 | c.1584C>T p.T528= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as rs1189962591, COSV99530073; called by muse, mutect2
- TAF3 | c.*1C>T | 3'UTR (SNP) | VAF 8/188 reads (4%) | catalogued as COSV60212263; called by muse, mutect2
